Somatic mutation profile of tumor specimen MP2PRT-PAVERF-TMP1-B (aliquot MP2PRT-PAVERF-TMP1-B-1-0-D-A835-36) from MP2PRT case MP2PRT-PAVERF, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.1 years (771 days).
Specimen MP2PRT-PAVERF-TMP1-B: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6db081f3-e117-4210-9717-fa15e0dd52b9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAVERF-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAVERF-NB1-A-1-0-D-A835-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c0f6fa30-6406-43c5-a767-b62d997e1c88

The open-access MAF lists 8 somatic variants for this specimen: 4 protein-altering or splice-affecting, 4 silent.
By variant classification: Silent 4, Missense Mutation 2, In Frame Ins 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTPN11 | c.215C>T p.A72V | Missense Mutation (SNP) | VAF 167/470 reads (36%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen possibly damaging (0.806); catalogued as rs121918454, CM013417, COSV61005613, COSV61008344, COSV61012146; ClinVar: likely pathogenic / conflicting interpretations of pathogenicity; called by muse, varscan2
- SERPINA9 | c.834G>T p.K278N | Missense Mutation (SNP) | VAF 157/433 reads (36%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.77); catalogued as COSV100098638; called by muse, mutect2, varscan2
- CCND3 | c.862_863insTGC p.T288delinsMP | In Frame Ins (INS) | VAF 112/768 reads (15%) | called by pindel, varscan2
- TRPM6 | c.3744del p.K1248Nfs*15 | Frame Shift Del (DEL) | VAF 132/413 reads (32%) | called by mutect2, pindel, varscan2
- CYP46A1 | c.1494C>A p.P498= | Silent (SNP) | VAF 31/662 reads (5%) | catalogued as rs988109980; called by muse, mutect2
- DRC7 | c.1302C>T p.N434= | Silent (SNP) | VAF 112/303 reads (37%) | catalogued as rs764125087, COSV100395971; called by muse, mutect2
- NT5C1B | c.543G>A p.A181= (on ENST00000359846 / NM_001199086.2; = p.A121= on NM_033253.4) | Silent (SNP) | VAF 317/756 reads (42%) | catalogued as COSV58394988; called by muse, varscan2
- SALL3 | c.3249C>T p.G1083= | Silent (SNP) | VAF 420/986 reads (43%) | catalogued as rs774736357; called by muse, varscan2
